Somatic mutation profile of tumor specimen TCGA-L9-A444-01A (aliquot TCGA-L9-A444-01A-21D-A24D-08) from TCGA case TCGA-L9-A444, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 60.8 years (22,202 days).
Specimen TCGA-L9-A444-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0307f560-777b-4492-bffd-8eacae8da208.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L9-A444-10A (Blood Derived Normal), aliquot TCGA-L9-A444-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8796b76-d1b1-4bbf-b6b1-f06cb3b3ee53

The open-access MAF lists 610 somatic variants for this specimen: 450 protein-altering or splice-affecting, 144 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 389, Silent 144, Nonsense Mutation 32, Frame Shift Del 14, Splice Site 10, RNA 6, Intron 4, Frame Shift Ins 4, 5'UTR 3, 3'UTR 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 31/100 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs587782705, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASDH | c.2461T>C p.S821P | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99221299; called by muse, mutect2, varscan2
- ABCA13 | c.11794G>A p.V3932I | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as rs201412160; called by muse, mutect2, varscan2
- ABCB11 | c.2545G>A p.D849N | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.376); catalogued as COSV55593398, COSV99792236; called by muse, mutect2, varscan2
- ABCB7 | c.302G>C p.G101A (on ENST00000373394 / NM_001271696.3; = p.G102A on NM_004299.6) | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV53718589, COSV99504376; called by muse, mutect2, varscan2
- AC134980.2 | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100171703; called by mutect2, varscan2
- AC244197.3 | c.90G>T p.L30F | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100558010; called by muse, mutect2, varscan2
- ACBD5 | c.394G>A p.E132K (on ENST00000375888 / NM_001352568.1; = p.E134K on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as COSV101022547; called by muse, mutect2, varscan2
- ACSM5 | c.1516C>A p.P506T | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100088946; called by muse, mutect2
- ACTG1 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV100111939; called by muse, mutect2, varscan2
- ACTL7A | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as COSV61776734; called by muse, mutect2, varscan2
- ACTN3 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.329); catalogued as rs1384786701, COSV101557838; called by muse, mutect2
- ADAM2 | c.1288G>C p.G430R | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55870177, COSV99697341; called by muse, mutect2, varscan2
- ADAM30 | c.290G>C p.G97A | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV101023872; called by muse, mutect2, varscan2
- ADAMTS12 | c.1205A>G p.H402R | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100710971; called by muse, mutect2, varscan2
- ADAMTS17 | c.1646G>T p.W549L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV99170702; called by muse, mutect2, varscan2
- ADAMTS19 | c.3141G>T p.E1047D | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.5); catalogued as COSV99178833; called by muse, mutect2, varscan2
- ADAMTS2 | c.2790T>A p.C930* | Nonsense Mutation (SNP) | VAF 46/152 reads (30%) | catalogued as COSV99282263; called by muse, mutect2, varscan2
- ADAMTS4 | c.1338C>A p.D446E | Missense Mutation (SNP) | VAF 124/220 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV100917755; called by muse, mutect2, varscan2
- ADAMTS7 | c.506A>T p.D169V | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.345); catalogued as COSV101183105; called by muse, mutect2, varscan2
- ADCY5 | c.3559G>T p.G1187W | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100567134, COSV100567373; called by muse, mutect2, varscan2
- ADGRB3 | c.782C>T p.T261I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.969); catalogued as COSV101000772; called by muse, mutect2, varscan2
- ADGRF2 | c.1733C>A p.T578N (on ENST00000296862 / NM_001368115.2; = p.T510N on NM_153839.7) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99731267; called by muse, mutect2, varscan2
- ADGRF4 | c.230C>A p.T77K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as COSV99348405; called by muse, mutect2, varscan2
- ADGRF4 | c.1609A>T p.T537S | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99348407; called by muse, mutect2
- AHR | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 9/92 reads (10%) | catalogued as COSV99619731; called by muse, mutect2, varscan2
- AK8 | c.854C>A p.A285D | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100050033; called by muse, mutect2, varscan2
- ALDH1B1 | c.56A>G p.Y19C | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.614); catalogued as COSV100890945; called by muse, mutect2
- ALPK3 | c.2543C>A p.P848Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV99360954; called by muse, mutect2, varscan2
- AMBRA1 | c.2856G>T p.M952I (on ENST00000458649 / NM_001367468.1; = p.M862I on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV100094004; called by muse, mutect2
- ANK2 | c.2826G>T p.R942S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.337); catalogued as rs771898745, COSV100001724; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD17 | c.7757G>A p.W2586* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100429231; called by muse, mutect2, varscan2
- ANTXR1 | c.1072C>G p.P358A | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1468067247, COSV100362527; called by muse, mutect2, varscan2
- APCDD1L | c.1202C>A p.P401Q | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV100953990; called by muse, mutect2, varscan2
- ARHGAP36 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52269714, COSV99357717; called by muse, mutect2, varscan2
- ARID1B | c.1564G>T p.V522L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.057); catalogued as COSV99269249; called by muse, mutect2, varscan2
- ARMCX6 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV100726230; called by muse, mutect2, varscan2
- ARPP19 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99992927; called by muse, mutect2, varscan2
- ARSH | c.1680G>T p.M560I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV101139863; called by mutect2, varscan2
- ARSH | c.1681G>T p.A561S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.039); catalogued as COSV101139864, COSV66962545; called by mutect2, varscan2
- ASB16 | c.1297C>G p.R433G | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV53235912; called by muse, mutect2, varscan2
- ASB9 | c.602C>A p.S201Y | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100995512; called by muse, mutect2, varscan2
- ASIC2 | c.410T>C p.L137P | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100726410; called by muse, mutect2, varscan2
- ASXL3 | c.4718C>A p.T1573N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.05); catalogued as COSV99324982; called by muse, mutect2, varscan2
- ATAD1 | c.660G>T p.W220C | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100058203; called by muse, mutect2, varscan2
- ATP6V1H | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100778643; called by muse, mutect2, varscan2
- ATP8B4 | c.1077G>T p.W359C | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV99465569; called by muse, mutect2
- ATP8B4 | c.1076G>T p.W359L | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99465572; called by muse, mutect2
- BATF2 | c.256A>G p.M86V | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100101780; called by muse, mutect2, varscan2
- BBX | c.326G>C p.G109A | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100361593, COSV57890578; called by muse, mutect2, varscan2
- BCHE | c.1648T>A p.W550R | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52257961, COSV52258796; called by muse, mutect2
- BCOR | c.2023G>T p.G675C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV100653334; called by muse, mutect2, varscan2
- BHLHE22 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100417766; called by muse, mutect2, varscan2
- BNC2 | c.1472C>G p.A491G | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV101033283; called by muse, mutect2, varscan2
- BPI | c.133C>A p.L45M (on ENST00000262865; = p.L41M on NM_001725.3) | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99480649; called by muse, mutect2, varscan2
- BPIFC | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55911620; called by muse, mutect2, varscan2
- C18orf25 | c.1085G>A p.G362D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.255); catalogued as COSV99960026; called by mutect2, varscan2
- C3 | c.2441G>T p.G814V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99836663; called by muse, mutect2, varscan2
- CACNA1E | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV100702725; called by muse, mutect2
- CACNA1F | c.5281G>T p.E1761* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100544883; called by muse, mutect2, varscan2
- CCDC105 | c.1249C>A p.Q417K | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.765); catalogued as COSV99479909; called by muse, mutect2, varscan2
- CCL7 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.6); catalogued as COSV99565556, COSV99565639; called by muse, mutect2, varscan2
- CDH5 | c.1885C>A p.R629S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.036); catalogued as rs745948376, COSV100439238; called by muse, mutect2, varscan2
- CDHR1 | c.1966G>T p.V656L | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs142045222, COSV100258888; called by muse, mutect2, varscan2
- CFAP53 | c.1468G>A p.V490I | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101274987; called by muse, mutect2
- CHD5 | c.5587C>A p.Q1863K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV99313656; called by muse, mutect2, varscan2
- CHIA | c.1255A>T p.S419C (on ENST00000343320; = p.S311C on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV100588675; called by muse, mutect2, varscan2
- CHIT1 | c.760G>T p.G254W | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99705201; called by muse, mutect2, varscan2
- CHL1 | c.3332A>T p.Y1111F (on ENST00000397491 / NM_001253387.1; = p.Y1127F on NM_006614.4) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99851257; called by muse, mutect2, varscan2
- CIAO1 | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51497110, COSV99302619; called by muse, mutect2, varscan2
- CISD1 | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100445717, COSV61703184; called by mutect2, varscan2
- CKM | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as rs771688624, COSV99675424, COSV99675550; called by muse, mutect2, varscan2
- CLCA2 | c.2206G>C p.E736Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0.084); catalogued as COSV100991540; called by muse, mutect2, varscan2
- CLCN1 | c.1432C>A p.P478T | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100578078; called by muse, mutect2, varscan2
- CLDN17 | c.221C>A p.P74Q | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99729077; called by muse, mutect2, varscan2
- CLEC9A | c.329G>T p.S110I | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100872814, COSV63349231; called by muse, mutect2
- CLIP2 | c.98C>A p.A33E | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as COSV99791592; called by muse, mutect2, varscan2
- CLSPN | c.2120G>T p.G707V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV99230924; called by muse, mutect2, varscan2
- CLUH | c.3884C>T p.S1295F (on ENST00000435359; = p.S1334F on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.485); catalogued as rs1447749888, COSV70928678; called by muse, mutect2, varscan2
- CNTLN | c.1757G>T p.G586V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV99264164; called by muse, mutect2
- COL12A1 | c.7774G>T p.D2592Y | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV100486007; called by muse, mutect2, varscan2
- COL15A1 | c.3778G>T p.D1260Y | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100897691; called by muse, mutect2, varscan2
- COL1A2 | c.2066C>A p.A689D | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV51955839, COSV99799781; called by muse, mutect2, varscan2
- COL4A2 | c.742C>G p.P248A | Missense Mutation (SNP) | VAF 68/126 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100847350; called by muse, mutect2, varscan2
- COL7A1 | c.8210G>T p.G2737V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99866276; called by muse, mutect2, varscan2
- COL7A1 | c.8209G>T p.G2737* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as CM060930, COSV99866277; called by muse, mutect2, varscan2
- COL9A1 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.536); catalogued as COSV100611467; called by muse, mutect2, varscan2
- CPA6 | c.669G>T p.M223I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV52736558, COSV99913636; called by muse, mutect2, varscan2
- CPS1 | c.242C>A p.P81Q | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99243066; called by muse, mutect2, varscan2
- CRB2 | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV100749644; called by muse, mutect2, varscan2
- CSMD3 | c.5261C>A p.A1754D (on ENST00000297405 / NM_001363185.1; = p.A1650D on NM_052900.3) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.609); catalogued as COSV99834806, COSV99840777; called by muse, mutect2, varscan2
- CSMD3 | c.4471C>A p.P1491T (on ENST00000297405 / NM_001363185.1; = p.P1387T on NM_052900.3) | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV52181393, COSV99834808; called by muse, mutect2
- CSMD3 | c.2003G>T p.G668V (on ENST00000297405 / NM_001363185.1; = p.G564V on NM_052900.3) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99834810; called by muse, varscan2
- CSPP1 | c.534+1G>T p.X178_splice (on ENST00000676605; = p.X137_splice on NM_024790.6) | Splice Site (SNP) | VAF 11/40 reads (28%) | catalogued as COSV99138581; called by muse, mutect2, varscan2
- DACT1 | c.1604G>T p.R535M | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100241868; called by muse, mutect2
- DCC | c.613G>T p.G205W | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100500165; called by muse, mutect2, varscan2
- DCX | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100576458; called by muse, mutect2, varscan2
- DENND2C | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs1379412803, COSV67923884; called by muse, mutect2, varscan2
- DHX40 | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs796835899, COSV99233012; called by muse, mutect2, varscan2
- DIAPH2 | c.2869C>A p.Q957K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV100232919; called by muse, mutect2, varscan2
- DKC1 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV101059882; called by muse, mutect2, varscan2
- DMBT1 | c.3014G>T p.R1005L (on ENST00000338354 / NM_001377530.1; = p.R506L on NM_004406.3) | Missense Mutation (SNP) | VAF 66/456 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100352985, COSV57536368; called by muse, mutect2, varscan2
- DMD | c.2281G>T p.E761* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as CM0910025, COSV99922561; called by muse, mutect2, varscan2
- DNAH9 | c.2887G>T p.V963L | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV99305918; called by muse, mutect2, varscan2
- DNASE2B | c.890C>A p.S297Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.656); catalogued as COSV101042025; called by muse, mutect2, varscan2
- DOCK2 | c.2788C>A p.H930N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.027); catalogued as COSV56940281, COSV99912509; called by muse, mutect2, varscan2
- DPH7 | c.1073G>T p.S358I | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV99483546; called by muse, mutect2
- DPP3 | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 33/79 reads (42%) | catalogued as COSV64756549, COSV64758166; called by muse, mutect2, varscan2
- DUSP9 | c.1079C>A p.A360E | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61438053; called by muse, mutect2
- EFHC2 | c.397C>A p.R133S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101375475; called by muse, mutect2
- EIF2AK3 | c.2414C>T p.S805L | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1301049321, COSV100303731; called by muse, mutect2, varscan2
- EIF4E2 | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99298948, COSV99299113; called by muse, mutect2, varscan2
- ELAPOR2 | c.1110G>A p.W370* (on ENST00000450689 / NM_001142749.3; = p.W203* on NM_152748.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as rs1034912558, COSV99788799; called by muse, mutect2
- ELOA2 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.067); catalogued as COSV99796653; called by muse, mutect2, varscan2
- ELOVL3 | c.258G>C p.W86C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.752); catalogued as COSV100892798; called by muse, mutect2, varscan2
- EOGT | c.1468A>T p.K490* (on ENST00000383701 / NM_001278689.2; = p.K406* on NM_173654.3) | Nonsense Mutation (SNP) | VAF 3/30 reads (10%) | catalogued as COSV99808881; called by muse, mutect2
- ERICH3 | c.1267G>T p.E423* | Nonsense Mutation (SNP) | VAF 28/85 reads (33%) | catalogued as COSV58614434; called by muse, mutect2, varscan2
- ETNPPL | c.1303+2T>A p.X435_splice | Splice Site (SNP) | VAF 4/20 reads (20%) | catalogued as COSV56597865, COSV99625260; called by muse, mutect2
- EXOC4 | c.2748G>T p.Q916H | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.801); catalogued as COSV99553971; called by muse, mutect2, varscan2
- FAM133A | c.616del p.A206Qfs*17 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | catalogued as COSV59075939; called by mutect2, varscan2
- FAM155B | c.403G>T p.G135C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99368398; called by muse, mutect2, varscan2
- FAM180A | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV100647285; called by muse, mutect2, varscan2
- FAM20B | c.58A>T p.T20S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.054); catalogued as COSV99762361; called by muse, mutect2, varscan2
- FAM217B | c.861A>T p.E287D | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV100674534; called by muse, mutect2, varscan2
- FAM47A | c.497G>T p.C166F | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100649903; called by muse, mutect2, varscan2
- FAM47B | c.268C>A p.R90S | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100264090, COSV61453106; called by muse, mutect2, varscan2
- FAM47C | c.2371C>G p.P791A | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100792566; called by muse, mutect2, varscan2
- FAM9A | c.132G>A p.M44I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.133); catalogued as COSV101121344; called by muse, mutect2, varscan2
- FARS2 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs150490093; called by muse, mutect2, varscan2
- FBH1 | c.2863G>A p.V955I (on ENST00000362091 / NM_178150.3; = p.V1006I on NM_032807.4) | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs141977640, COSV62981650; called by muse, mutect2, varscan2
- FER1L6 | c.5185G>T p.D1729Y | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.534); catalogued as COSV101205869; called by muse, mutect2, varscan2
- FGFR2 | c.1173G>T p.M391I | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV100336241; called by muse, mutect2, varscan2
- FLG | c.5963G>T p.G1988V | Missense Mutation (SNP) | VAF 144/1910 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.336); catalogued as COSV100911596; called by muse, mutect2
- FLG | c.5962G>T p.G1988* | Nonsense Mutation (SNP) | VAF 142/1899 reads (7%) | catalogued as COSV64236260; called by muse, mutect2
- FLG | c.5529C>A p.H1843Q | Missense Mutation (SNP) | VAF 73/1662 reads (4%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.917); catalogued as COSV100911597; called by muse, mutect2
- FMOD | c.535A>T p.R179* | Nonsense Mutation (SNP) | VAF 61/199 reads (31%) | catalogued as COSV100724552; called by muse, mutect2, varscan2
- FRMPD4 | c.2108C>A p.P703Q | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.093); catalogued as COSV101042925; called by muse, mutect2
- FUT9 | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100133648; called by muse, mutect2, varscan2
- G6PD | c.1249G>T p.E417* | Nonsense Mutation (SNP) | VAF 41/279 reads (15%) | catalogued as COSV63704461; called by muse, mutect2, varscan2
- GABRA2 | c.787A>G p.M263V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100734280; called by muse, mutect2, varscan2
- GABRR1 | c.178A>G p.I60V | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV101033916; called by muse, mutect2, varscan2
- GABRR2 | c.1228C>A p.H410N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.334); catalogued as COSV101298961; called by mutect2, varscan2
- GAD2 | c.690G>T p.W230C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52162227, COSV99393277; called by muse, mutect2, varscan2
- GALNTL6 | c.458G>T p.W153L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.439); catalogued as COSV101487754; called by muse, mutect2, varscan2
- GFRA3 | c.597G>T p.Q199H | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.903); catalogued as COSV99218388; called by muse, mutect2, varscan2
- GFRAL | c.823T>A p.C275S | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100475182; called by muse, mutect2, varscan2
- GIMAP1 | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100212111; called by muse, mutect2, varscan2
- GK | c.746T>A p.V249E | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV100970855; called by muse, mutect2, varscan2
- GPR179 | c.518C>A p.T173N | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs757737139; called by muse, mutect2
- GPR45 | c.615C>G p.F205L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.487); catalogued as COSV99306969, COSV99307232; called by muse, mutect2, varscan2
- GPR6 | c.1027C>A p.L343M | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV99254344; called by muse, mutect2, varscan2
- GRIK2 | c.2621G>C p.R874P | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.749); catalogued as COSV100026245, COSV59726325; called by muse, mutect2, varscan2
- GRM7 | c.919C>A p.H307N | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100736619; called by muse, mutect2, varscan2
- H2AC13 | c.34C>G p.R12G | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.231); catalogued as rs1215183811, COSV100704385, COSV62440550; called by muse, mutect2, varscan2
- HAX1 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 34/281 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs373783109; called by muse, mutect2, varscan2
- HCK | c.1300T>A p.F434I | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99394076; called by muse, mutect2, varscan2
- HCN1 | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100300307, COSV57498987; called by muse, mutect2, varscan2
- HCN1 | c.260C>A p.P87H | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as rs1397144091, COSV100300308; called by muse, mutect2, varscan2
- HEPACAM | c.773C>A p.T258K | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100005717, COSV53432259; called by muse, mutect2, varscan2
- HERC6 | c.2211G>A p.M737I | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV99986661; called by muse, mutect2, varscan2
- HIPK1 | c.2609G>T p.G870V | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.963); catalogued as COSV100479104; called by muse, mutect2, varscan2
- HK2 | c.1989G>T p.M663I | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as COSV99309058; called by muse, mutect2, varscan2
- HMGCS1 | c.143C>G p.T48S | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV100285004; called by muse, mutect2, varscan2
- HOXD10 | c.161T>A p.L54H | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV99982760; called by muse, mutect2, varscan2
- HPGD | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99640399; called by muse, mutect2, varscan2
- HS3ST2 | c.659C>A p.S220Y | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99758120; called by muse, mutect2, varscan2
- HTR7 | c.973G>C p.A325P | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99519605; called by muse, mutect2, varscan2
- HUWE1 | c.8216C>T p.P2739L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.011); catalogued as COSV99472432; called by muse, mutect2, varscan2
- IDI1 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 13/102 reads (13%) | catalogued as COSV101191224; called by muse, mutect2, varscan2
- IGHG3 | c.915C>A p.S305R | Missense Mutation (SNP) | VAF 75/273 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.371); catalogued as rs185410106; called by muse, mutect2, varscan2
- IGSF21 | c.356G>C p.G119A | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52140012, COSV99244881; called by muse, mutect2, varscan2
- IKZF1 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); catalogued as rs1353402014, COSV100498397; called by muse, mutect2, varscan2
- IL10RA | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57139303, COSV99923106; called by muse, mutect2, varscan2
- IL12B | c.914G>T p.S305I | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV99180341; called by muse, mutect2, varscan2
- IL31RA | c.1239G>T p.W413C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759956809, COSV99763141; called by muse, mutect2, varscan2
- ILDR1 | c.508A>T p.T170S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99878361; called by muse, mutect2, varscan2
- ILDR2 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV99613909; called by muse, mutect2, varscan2
- INO80C | c.450C>T p.A150= | Splice Region (SNP) | VAF 20/100 reads (20%) | catalogued as COSV100577225; called by muse, mutect2, varscan2
- INSYN2A | c.62C>A p.A21D | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV54732841; called by muse, mutect2, varscan2
- ITGA10 | c.2936G>A p.C979Y | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.173); catalogued as COSV100994912; called by muse, mutect2
- ITGB1BP2 | c.988G>C p.D330H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV99338864; called by muse, mutect2, varscan2
- ITIH6 | c.2093C>G p.S698* | Nonsense Mutation (SNP) | VAF 8/95 reads (8%) | catalogued as COSV99513323; called by muse, mutect2
- JARID2 | c.356A>T p.Q119L | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100521899; called by muse, mutect2, varscan2
- KANK4 | c.1601G>A p.G534E | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as COSV100587377; called by muse, mutect2
- KAT6A | c.4312G>T p.E1438* | Nonsense Mutation (SNP) | VAF 22/182 reads (12%) | catalogued as COSV99705137; called by muse, mutect2, varscan2
- KCNA10 | c.843G>T p.W281C | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769185254, COSV100871433; called by muse, mutect2, varscan2
- KCNB2 | c.578A>T p.K193M | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV101578788; called by muse, mutect2, varscan2
- KDM2A | c.2525C>T p.A842V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.264); catalogued as rs1216483801, COSV100445618; called by muse, mutect2, varscan2
- KDR | c.3286T>C p.W1096R | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99817765; called by muse, mutect2, varscan2
- KHDC3L | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.06); catalogued as COSV64859303; called by muse, mutect2
- KIAA1549L | c.431C>A p.A144E (on ENST00000321505; = p.A441E on NM_012194.3) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV99683527; called by muse, mutect2, varscan2
- KIF26B | c.1231G>T p.A411S | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV100832455, COSV63646818; called by muse, mutect2, varscan2
- KIF26B | c.1232C>G p.A411G | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV100832459; called by muse, mutect2, varscan2
- KIF2B | c.850G>C p.A284P | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs776017105, COSV52129130; called by muse, mutect2, varscan2
- KIF6 | c.34G>T p.V12L | Missense Mutation (SNP) | VAF 99/340 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs773227128, COSV99758898; called by muse, mutect2, varscan2
- KIR2DL1 | c.251A>C p.N84T | Missense Mutation (SNP) | VAF 82/448 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.167); catalogued as COSV99383104; called by muse, varscan2
- KLF4 | c.1432C>A p.H478N | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101012695; called by muse, mutect2
- KMT2B | c.6997G>T p.G2333W | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99719669; called by muse, mutect2, varscan2
- KMT2D | c.781A>T p.T261S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV99981978; called by muse, mutect2, varscan2
- KNTC1 | c.5878G>T p.A1960S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100338343; called by muse, mutect2
- KPRP | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 31/338 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100908703, COSV64221042; called by muse, mutect2
- KPRP | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.272); catalogued as COSV100908704, COSV64222577; called by muse, mutect2, varscan2
- KRTAP24-1 | c.601C>A p.Q201K | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.115); catalogued as COSV100447421; called by muse, mutect2, varscan2
- KRTAP24-1 | c.470G>T p.C157F | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.25); catalogued as COSV100447423; called by muse, mutect2, varscan2
- KRTAP26-1 | c.547C>A p.L183I | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.401); catalogued as COSV100860418; called by muse, mutect2
- KRTAP26-1 | c.546C>A p.S182R | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV100860419; called by muse, mutect2
- KRTAP27-1 | c.179G>C p.C60S | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.125); catalogued as COSV101239724; called by muse, mutect2, varscan2
- LAMA4 | c.2677G>C p.E893Q (on ENST00000230538 / NM_001105206.3; = p.E886Q on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV100038404; called by muse, mutect2
- LAMB2 | c.2891G>T p.R964L | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774551290, COSV100026179, COSV59731348; called by muse, mutect2
- LCE1A | c.92C>A p.P31Q | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.943); catalogued as COSV100632068, COSV58727843; called by muse, mutect2
- LCE1D | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 22/368 reads (6%) | PolyPhen benign (0); catalogued as COSV100405895; called by muse, mutect2
- LCE1F | c.40C>G p.P14A | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100542720, COSV100542743, COSV57669589; called by muse, mutect2
- LDLRAD4 | c.675C>A p.S225R | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.009); catalogued as COSV100762195, COSV63343707; called by muse, mutect2, varscan2
- LRFN2 | c.385C>G p.L129V | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100599583; called by muse, mutect2, varscan2
- LRP1B | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101257247; called by muse, mutect2
- LRRC19 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV101195795; called by muse, mutect2, varscan2
- LRRC66 | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as COSV100602965; called by muse, mutect2
- LRRC66 | c.349A>T p.S117C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100602966; called by muse, mutect2, varscan2
- LRRIQ1 | c.2578T>G p.L860V | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101280356; called by muse, mutect2
- M1AP | c.698A>C p.D233A | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99304093; called by muse, mutect2, varscan2
- MAGEA11 | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 58/284 reads (20%) | catalogued as COSV60756890, COSV60758990; called by muse, mutect2
- MAGEA6 | c.456C>G p.S152R | Missense Mutation (SNP) | VAF 78/233 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as rs782691116, COSV100262824; called by muse, mutect2, varscan2
- MAGEB10 | c.1009A>T p.K337* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100775276; called by muse, mutect2, varscan2
- MAGEC1 | c.1004A>T p.Q335L | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV99595732; called by muse, varscan2
- MAGEC1 | c.3407C>A p.S1136Y | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.103); catalogued as COSV99595736; called by muse, mutect2, varscan2
- MAGEC3 | c.1543G>T p.D515Y | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100025416, COSV100025971; called by muse, mutect2, varscan2
- MAP3K15 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV58829479; called by muse, mutect2, varscan2
- MARK1 | c.2111G>A p.W704* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100857258; called by muse, mutect2, varscan2
- MAST3 | c.2183G>C p.S728T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.621); catalogued as rs748649520, COSV99445333; called by muse, varscan2
- MEP1A | c.1579T>C p.F527L | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.09); catalogued as COSV100042741; called by muse, mutect2
- MGA | c.4150G>T p.G1384C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54961141; called by muse, mutect2, varscan2
- MGAT3 | c.895G>T p.D299Y | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV100361886; called by muse, mutect2, varscan2
- MKLN1 | c.1232G>T p.C411F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100759829, COSV61760125; called by muse, mutect2, varscan2
- MON2 | c.1982C>T p.P661L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.929); catalogued as rs748022548, COSV99742605; called by muse, mutect2, varscan2
- MPEG1 | c.1061A>G p.N354S | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99915447; called by muse, mutect2, varscan2
- MROH7 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100273495; called by muse, mutect2, varscan2
- MS4A14 | c.719C>A p.S240Y | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.302); catalogued as COSV100280437; called by muse, mutect2, varscan2
- MS4A2 | c.580G>C p.G194R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.837); catalogued as COSV99627280; called by muse, mutect2, varscan2
- MS4A2 | c.581G>A p.G194D | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.773); catalogued as rs1167619732, COSV99627284; called by muse, mutect2, varscan2
- MS4A4A | c.41G>T p.S14I | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100557810; called by mutect2, varscan2
- MS4A4A | c.41+1G>T p.X14_splice | Splice Site (SNP) | VAF 4/54 reads (7%) | catalogued as COSV100557811; called by muse, mutect2
- MTHFD1L | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as COSV100943476; called by muse, mutect2, varscan2
- MTMR3 | c.1341G>T p.M447I | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV100070866; called by muse, mutect2, varscan2
- MUC16 | c.34015G>T p.E11339* | Nonsense Mutation (SNP) | VAF 33/88 reads (38%) | catalogued as COSV101199979, COSV67461111; called by muse, mutect2, varscan2
- MUC16 | c.32876C>T p.P10959L | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV101199980; called by muse, mutect2, varscan2
- MUC16 | c.15055A>C p.M5019L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV101199981; called by muse, mutect2, varscan2
- MXRA5 | c.8372C>A p.P2791H | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99477032; called by muse, mutect2
- MXRA5 | c.8224G>A p.V2742I | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV99477037; called by muse, mutect2, varscan2
- MYEOV | c.720C>A p.H240Q | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV58294959; called by muse, mutect2, varscan2
- MYH14 | c.5407G>T p.G1803W | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99222749; called by muse, mutect2, varscan2
- MYH4 | c.169G>T p.G57W | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs780288488, COSV99700961, COSV99701309; called by muse, mutect2, varscan2
- MYH6 | c.3383G>A p.R1128H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs376002621; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH6 | c.1798G>A p.D600N | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100676598; called by muse, mutect2, varscan2
- NAA15 | c.1588A>T p.M530L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.139); catalogued as COSV99649564; called by muse, mutect2, varscan2
- NBAS | c.4966G>T p.D1656Y | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99869807; called by muse, mutect2, varscan2
- NCKAP1L | c.1000G>T p.G334C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99515106; called by muse, mutect2, varscan2
- NCKAP5 | c.2725C>A p.P909T | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as COSV100492179; called by muse, mutect2, varscan2
- NEGR1 | c.288G>C p.L96F | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as COSV60840264; called by muse, mutect2, varscan2
- NF1 | c.7189G>T p.G2397W (on ENST00000358273 / NM_001042492.3; = p.G2376W on NM_000267.3) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CS155065, COSV100647103; called by muse, mutect2, varscan2
- NHSL2 | c.1870C>T p.Q624* (on ENST00000510661; = p.Q990* on NM_001013627.2) | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV101030110; called by muse, mutect2
- NLRP9 | c.1049G>T p.R350M | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV100243082; called by muse, mutect2, varscan2
- NRCAM | c.1576G>T p.V526F (on ENST00000379028 / NM_001371124.1; = p.V520F on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.274); catalogued as rs374383279, COSV100694721; called by mutect2, varscan2
- NRXN1 | c.1046G>T p.G349V | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100454072, COSV100455221; called by muse, mutect2, varscan2
- NTNG1 | c.155C>A p.P52Q | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99637493; called by muse, mutect2, varscan2
- NUTM2D | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as COSV101096946; called by muse, mutect2, varscan2
- OFD1 | c.2841A>G p.I947M | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100366221; called by muse, mutect2, varscan2
- OLFM4 | c.130T>G p.S44A | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.026); catalogued as COSV99524340; called by muse, mutect2, varscan2
- OPRM1 | c.109T>A p.L37I | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100001386; called by muse, mutect2, varscan2
- OR11H6 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs946398048, COSV59643724; called by muse, mutect2, varscan2
- OR13C5 | c.10del p.E4Kfs*11 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | catalogued as COSV66164546; called by mutect2, pindel, varscan2
- OR14I1 | c.368C>A p.A123D | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100700483; called by muse, mutect2, varscan2
- OR1C1 | c.140C>A p.A47E | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as rs372819870, COSV101376227; called by muse, mutect2, varscan2
- OR1S1 | c.139A>T p.M47L | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100515401; called by muse, mutect2, varscan2
- OR1S2 | c.14G>T p.C5F | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV100224216; called by mutect2, varscan2
- OR2AK2 | c.100C>A p.L34I | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100823702, COSV63557679; called by muse, mutect2, varscan2
- OR2H1 | c.929G>C p.R310T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV101009868; called by muse, mutect2
- OR2M3 | c.242T>A p.M81K | Missense Mutation (SNP) | VAF 112/418 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV101513432, COSV99081721; called by muse, mutect2, varscan2
- OR2M4 | c.74C>A p.T25N | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.439); catalogued as rs1450977935, COSV100141241; called by muse, mutect2, varscan2
- OR2M5 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 79/346 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63546139; called by muse, mutect2, varscan2
- OR3A1 | c.856C>A p.P286T | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100041687; called by muse, mutect2, varscan2
- OR4C15 | c.1025T>C p.F342S (on ENST00000314644; = p.F288S on NM_001001920.2) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); catalogued as COSV100115692; called by muse, mutect2, varscan2
- OR4E2 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1371117158, COSV100330101; called by muse, mutect2, varscan2
- OR52M1 | c.332C>A p.T111N | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as COSV100798585; called by muse, mutect2, varscan2
- OR56A3 | c.87C>A p.H29Q | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100290236; called by muse, mutect2, varscan2
- OR5B12 | c.30C>G p.F10L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100222437; called by muse, mutect2, varscan2
- OR5B17 | c.320C>A p.T107N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV100641901; called by muse, mutect2
- OR5T2 | c.937G>T p.V313L | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV57589547; called by muse, mutect2, varscan2
- OR6Q1 | c.340A>C p.T114P | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs777671182, COSV100109976; called by muse, mutect2
- OR8H3 | c.614C>A p.S205Y | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.836); catalogued as COSV57909156; called by muse, mutect2, varscan2
- OSBPL11 | c.1477A>C p.T493P | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as COSV99954204; called by mutect2, varscan2
- P3H2 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 3/42 reads (7%) | catalogued as COSV100077724, COSV60025460; called by muse, mutect2
- PABPN1 | c.632A>T p.H211L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV99391167; called by muse, mutect2, varscan2
- PASD1 | c.1309C>A p.Q437K | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as COSV100949376; called by muse, mutect2, varscan2
- PCDH11X | c.3710C>T p.S1237L | Missense Mutation (SNP) | VAF 42/231 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs750521137, COSV100011823, COSV53497011; called by muse, mutect2, varscan2
- PCDH15 | c.4898G>T p.G1633V (on ENST00000644397 / NM_001354429.2; = p.G1575V on NM_001142771.2) | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100904458; called by muse, mutect2, varscan2
- PCDH15 | c.4897G>T p.G1633W (on ENST00000644397 / NM_001354429.2; = p.G1575W on NM_001142771.2) | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV100904459; called by muse, mutect2, varscan2
- PCDH8 | c.3110G>T p.R1037L | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100131644; called by muse, mutect2, varscan2
- PCDHA2 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.819); catalogued as rs782314094; called by muse, mutect2, varscan2
- PCDHB16 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV53368308, COSV53368641; called by muse, mutect2, varscan2
- PCNX1 | c.3782G>C p.R1261P | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV53097743, COSV99455659; called by muse, mutect2, varscan2
- PCSK5 | c.5557G>T p.D1853Y | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101377406; called by muse, mutect2, varscan2
- PDE3B | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99962595; called by muse, mutect2, varscan2
- PDZD2 | c.330G>T p.Q110H | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV99225018; called by muse, mutect2, varscan2
- PEG3 | c.172G>T p.V58F | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs140343570, COSV55632252; called by muse, mutect2, varscan2
- PFAS | c.1952A>G p.Q651R | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1482411875, COSV100118932; called by muse, mutect2, varscan2
- PGK2 | c.696T>G p.N232K | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV100505506; called by muse, mutect2, varscan2
- PGLYRP4 | c.559G>T p.V187F | Missense Mutation (SNP) | VAF 40/300 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.717); catalogued as COSV100668411; called by muse, mutect2
- PIGN | c.2134A>T p.S712C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100715858; called by muse, mutect2
- PIK3C2B | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as COSV100915030; called by muse, mutect2, varscan2
- PIK3CG | c.145C>G p.R49G | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.09); catalogued as rs774060880, COSV100782587, COSV100782895; called by muse, mutect2, varscan2
- PIKFYVE | c.4435A>T p.T1479S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100010741; called by muse, mutect2, varscan2
- PLXNB3 | c.3687G>T p.M1229I | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV100737460; called by muse, mutect2
- POLQ | c.1320G>T p.L440F | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99952277; called by muse, mutect2, varscan2
- POSTN | c.1392+1G>A p.X464_splice | Splice Site (SNP) | VAF 23/51 reads (45%) | catalogued as rs1261056968, COSV101123334; called by muse, mutect2, varscan2
- PPARGC1B | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs369256348; called by muse, mutect2, varscan2
- PPP1R3A | c.2731C>A p.Q911K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV99492974; called by muse, mutect2, varscan2
- PRDM12 | c.606C>A p.Y202* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as COSV99446213; called by muse, mutect2, varscan2
- PRKDC | c.1292A>T p.Y431F | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.248); catalogued as COSV100040680; called by muse, mutect2
- PRSS16 | c.1340A>T p.D447V | Missense Mutation (SNP) | VAF 62/218 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181984738, COSV100041750; called by muse, mutect2, varscan2
- PSG8 | c.958C>A p.R320S | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV100126217; called by muse, mutect2, varscan2
- PSKH2 | c.330C>G p.S110R | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV52611235, COSV99405172; called by muse, mutect2, varscan2
- PTCHD1 | c.1437G>T p.E479D | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT tolerated (0.9); PolyPhen benign (0.026); catalogued as COSV101037682; called by muse, mutect2, varscan2
- PTCHD4 | c.1208G>A p.S403N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.103); catalogued as COSV100260864; called by muse, mutect2
- PTGS1 | c.1317G>T p.M439I | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99793201; called by muse, mutect2, varscan2
- PTPRD | c.5011T>C p.F1671L | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV100644840; called by muse, mutect2, varscan2
- PXDNL | c.804A>G p.I268M | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.454); catalogued as COSV100683701; called by muse, mutect2, varscan2
- RAB6D | c.219A>T p.E73D | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV72151621; called by muse, mutect2, varscan2
- RABEPK | c.502A>T p.T168S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0.014); catalogued as COSV99413413; called by muse, mutect2, varscan2
- RAD50 | c.833G>T p.R278L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs587782307, COSV54750791, COSV99528969; ClinVar: uncertain significance; called by mutect2, varscan2
- RAPGEF4 | c.698+1G>T p.X233_splice | Splice Site (SNP) | VAF 18/62 reads (29%) | catalogued as COSV99910671; called by muse, mutect2, varscan2
- RASL12 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.161); catalogued as COSV99584964; called by muse, mutect2
- RB1CC1 | c.4181G>T p.S1394I | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as COSV99212260; called by muse, mutect2, varscan2
- RBM12 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.108); catalogued as COSV100467546; called by muse, mutect2
- REM1 | c.288G>T p.L96F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); catalogued as COSV52426780, COSV99147241; called by muse, mutect2, varscan2
- RGP1 | c.495G>T p.Q165H | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.381); catalogued as COSV100960221, COSV65239061; called by muse, mutect2, varscan2
- RGS1 | c.503C>A p.P168H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV100817485; called by muse, mutect2, varscan2
- RHAG | c.225T>A p.Y75* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as COSV100006612; called by muse, mutect2, varscan2
- RLN2 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV100395771; called by muse, mutect2, varscan2
- ROBO4 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100127604; called by muse, mutect2, varscan2
- RPIA | c.583A>G p.I195V | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.359); catalogued as COSV99376168; called by muse, mutect2, varscan2
- RPP40 | c.656G>T p.C219F | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV100123979; called by muse, mutect2
- SEC22A | c.595A>T p.S199C | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs1310058060, COSV100006991; called by muse, mutect2, varscan2
- SEC22A | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100006995; called by muse, mutect2, varscan2
- SEMA3A | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as COSV54888786, COSV54892439; called by muse, mutect2
- SEMA7A | c.1621T>G p.C541G | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV99984782; called by muse, mutect2
- SFTPA2 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 80/194 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100958782; called by muse, mutect2, varscan2
- SHPRH | c.5G>T p.S2I | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99262093; called by muse, mutect2, varscan2
- SI | c.1891G>T p.G631* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100015600; called by muse, mutect2
- SIPA1L2 | c.2244-1G>T p.X748_splice | Splice Site (SNP) | VAF 17/55 reads (31%) | catalogued as COSV99478297; called by muse, mutect2, varscan2
- SLC12A9 | c.1111G>T p.A371S | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99307845; called by muse, mutect2, varscan2
- SLC17A2 | c.744C>A p.H248Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV99614404; called by muse, mutect2, varscan2
- SLC27A6 | c.1621G>T p.V541F | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99322719; called by muse, mutect2, varscan2
- SLC5A1 | c.1923G>T p.W641C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99833434; called by muse, mutect2, varscan2
- SLC5A11 | c.1357T>C p.S453P | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV100762803, COSV61741871; called by muse, mutect2
- SLC6A18 | c.1192G>T p.G398W | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99722327; called by muse, mutect2, varscan2
- SLCO1C1 | c.130G>T p.V44L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as rs749971323, COSV99859153; called by muse, mutect2, varscan2
- SMR3B | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100513385, COSV59228651; called by muse, mutect2, varscan2
- SOD2 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100496545; called by muse, mutect2
- SPARC | c.383C>A p.T128K | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV99163794; called by muse, mutect2, varscan2
- SPEG | c.8480C>T p.P2827L | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1231610531, COSV100404531; called by muse, mutect2, varscan2
- SPIC | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV100162963; called by muse, mutect2, varscan2
- STAG2 | c.1911T>A p.H637Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV99493538; called by muse, mutect2, varscan2
- SUN1 | c.1145G>T p.R382L (on ENST00000405266 / NM_001367651.1; = p.R262L on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs368549213; called by muse, mutect2, varscan2
- SYNPO2 | c.3097C>A p.P1033T | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100205600; called by muse, mutect2, varscan2
- TAF1L | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs539151195, COSV99644745; called by muse, mutect2, varscan2
- TBC1D2 | c.2293G>T p.D765Y | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100579909; called by muse, mutect2, varscan2
- TBC1D2 | c.2292G>T p.Q764H | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100579911; called by muse, mutect2, varscan2
- TBC1D25 | c.1607C>A p.S536Y | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as rs1399430373, COSV100952162; called by muse, mutect2, varscan2
- TCOF1 | c.1201G>T p.A401S (on ENST00000377797 / NM_001135243.1; = p.A324S on NM_000356.4) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as COSV100077474; called by muse, mutect2, varscan2
- TCP11L2 | c.1196A>T p.E399V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100135347; called by muse, mutect2, varscan2
- TENM1 | c.4184G>C p.R1395P | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV100950060, COSV64437287; called by muse, mutect2, varscan2
- TENM1 | c.3929-1G>T p.X1310_splice | Splice Site (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100950061; called by muse, mutect2, varscan2
- TENM2 | c.4217G>C p.S1406T (on ENST00000518659 / NM_001122679.2; = p.S1167T on NM_001080428.3) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.867); catalogued as COSV101318693; called by muse, mutect2, varscan2
- TGFBR3 | c.706G>C p.E236Q | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99282969; called by muse, mutect2, varscan2
- THSD7A | c.951G>T p.W317C | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV101448709; called by muse, mutect2, varscan2
- TKFC | c.1102G>C p.G368R | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV99582464; called by muse, mutect2, varscan2
- TLDC2 | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV99455951; called by muse, mutect2, varscan2
- TLR6 | c.878G>C p.R293P | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV101126273; called by muse, mutect2
- TMPRSS11D | c.599G>C p.W200S | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99384677; called by muse, mutect2, varscan2
- TMPRSS15 | c.2143G>T p.V715F | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.531); catalogued as COSV99517986; called by muse, mutect2, varscan2
- TMPRSS3 | c.672G>C p.L224F | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.389); catalogued as rs1249784622, COSV99368092; called by muse, mutect2
- TRANK1 | c.1843G>T p.D615Y | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV57141240; called by muse, mutect2, varscan2
- TREX2 | c.539G>C p.R180P (on ENST00000334497; = p.R137P on NM_080701.3) | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.399); catalogued as rs781975770, COSV100444136; called by muse, mutect2
- TRIM17 | c.385C>A p.L129M | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV99694715; called by muse, mutect2, varscan2
- TRIM58 | c.923C>A p.A308D | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100825095; called by muse, mutect2, varscan2
- TRPC6 | c.2205+1G>A p.X735_splice | Splice Site (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100723629; called by muse, mutect2, varscan2
- TRPM2 | c.3051G>T p.R1017S | Missense Mutation (SNP) | VAF 63/454 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV100308815; called by muse, mutect2, varscan2
- TSHZ3 | c.2566G>A p.E856K | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.587); catalogued as COSV53666011; called by muse, mutect2, varscan2
- TSHZ3 | c.2201G>T p.G734V | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99551641; called by muse, mutect2, varscan2
- TSHZ3 | c.2200G>T p.G734C | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99551642; called by muse, mutect2, varscan2
- UGT1A1 | c.287G>C p.G96A | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV100530281; called by muse, mutect2, varscan2
- UGT3A1 | c.342G>T p.M114I | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV99954761; called by muse, mutect2, varscan2
- UMOD | c.187T>A p.C63S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM136330, COSV100208375; called by muse, mutect2, varscan2
- UNC13C | c.1399G>A p.V467M | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as rs1423934236, COSV99517577; called by muse, mutect2, varscan2
- UNC45B | c.2677G>T p.E893* | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | catalogued as COSV52092402, COSV99268713; called by muse, mutect2, varscan2
- USP51 | c.275A>G p.H92R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV101540667; called by muse, mutect2
- VGLL3 | c.865T>A p.S289T | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101051842; called by muse, mutect2
- VWA3B | c.1892C>A p.T631N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV68247282; called by muse, varscan2
- WASHC5 | c.3175A>T p.N1059Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV100572831; called by muse, mutect2, varscan2
- ZCCHC12 | c.665G>T p.W222L | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100038517; called by muse, mutect2, varscan2
- ZDHHC9 | c.222G>T p.M74I | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100852222; called by muse, mutect2, varscan2
- ZFP3 | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV100603805; called by muse, mutect2, varscan2
- ZFP42 | c.111G>T p.Q37H | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV58818995; called by muse, mutect2, varscan2
- ZIC1 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.074); catalogued as COSV99291940; called by muse, mutect2, varscan2
- ZIM2 | c.1105C>A p.P369T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.083); catalogued as COSV99689004; called by muse, mutect2, varscan2
- ZIM3 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.017); catalogued as COSV54140677; called by muse, mutect2
- ZIM3 | c.250G>T p.G84W | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99518117; called by muse, mutect2
- ZMYM3 | c.2718G>C p.L906F | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100077892, COSV100078060; called by muse, mutect2, varscan2
- ZNF182 | c.929G>T p.R310M | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100527053; called by muse, mutect2
- ZNF185 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV59278754; called by muse, mutect2, varscan2
- ZNF236 | c.2455A>T p.M819L | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99470375; called by muse, mutect2, varscan2
- ZNF335 | c.3124G>T p.A1042S | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.23); catalogued as COSV100533021; called by muse, mutect2, varscan2
- ZNF347 | c.67A>T p.T23S | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV100498300; called by muse, mutect2, varscan2
- ZNF449 | c.967C>A p.H323N | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100202975; called by muse, mutect2, varscan2
- ZNF474 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); catalogued as COSV99682158; called by muse, mutect2, varscan2
- ZNF540 | c.1864C>G p.L622V | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as COSV100329695; called by muse, mutect2, varscan2
- ZNF674 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.584); catalogued as COSV101345040; called by muse, mutect2
- ZNF706 | c.134G>C p.R45T | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV100245418; called by muse, mutect2, varscan2
- ZNF711 | c.1503G>C p.K501N | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99341209; called by muse, mutect2
- ZNF780B | c.2305G>C p.V769L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99665726; called by muse, mutect2, varscan2
- ZRANB2 | c.689G>T p.R230L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as COSV54673641, COSV99639379; called by muse, mutect2
- ZXDB | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as rs770015833, COSV66492981; called by muse, mutect2, varscan2
- ZZEF1 | c.8022G>T p.Q2674H | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV101067802; called by muse, mutect2, varscan2
- AHNAK2 | c.2751del p.V919Wfs*18 | Frame Shift Del (DEL) | VAF 98/368 reads (27%) | called by mutect2, pindel, varscan2
- AP1S1 | c.356dup p.M119Ifs*21 | Frame Shift Ins (INS) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- ARMCX2 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0); called by muse, mutect2
- BCKDHA | c.377del p.X126_splice | Splice Site (DEL) | VAF 21/81 reads (26%) | called by mutect2, pindel, varscan2
- C7 | c.143_144del p.R48Qfs*21 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel, varscan2
- CPZ | c.1858del p.R620Gfs*22 (on ENST00000360986 / NM_001014447.3; = p.R609Gfs*22 on NM_003652.3) | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | called by mutect2, pindel, varscan2
- DENND5B | c.1411dup p.M471Nfs*9 | Frame Shift Ins (INS) | VAF 16/125 reads (13%) | called by mutect2, pindel, varscan2
- IFNA8 | c.187dup p.Q63Pfs*5 | Frame Shift Ins (INS) | VAF 39/134 reads (29%) | called by mutect2, pindel, varscan2
- IGKV1-8 | c.46C>G p.P16A | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- IGKV1D-42 | c.53C>A p.P18Q | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- KIAA1549L | c.5423del p.L1808Rfs*11 (on ENST00000321505; = p.L2105Rfs*11 on NM_012194.3) | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | called by mutect2, pindel*, varscan2*
- KIAA1958 | c.731_732delinsT p.P244Lfs*4 | Frame Shift Del (DEL) | VAF 36/134 reads (27%) | called by pindel, varscan2*
- KIR2DS4 | c.300C>A p.C100* | Nonsense Mutation (SNP) | VAF 98/205 reads (48%) | called by muse, varscan2
- LCE1F | c.349T>G p.C117G | Missense Mutation (SNP) | VAF 7/187 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.334); called by muse, mutect2
- MAGEB6B | c.262G>C p.G88R | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- MRC1 | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MSL3 | c.1556del p.A519Efs*10 (on ENST00000312196 / NM_078629.4; = p.A353Efs*10 on NM_006800.4) | Frame Shift Del (DEL) | VAF 7/70 reads (10%) | called by mutect2, pindel, varscan2
- PRAMEF17 | c.440T>A p.L147* | Nonsense Mutation (SNP) | VAF 14/240 reads (6%) | called by muse, mutect2
- SOS2 | c.1259dup p.M420Ifs*3 | Frame Shift Ins (INS) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- TNFRSF25 | c.295+2T>G p.X99_splice | Splice Site (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- TPGS2 | c.570_572delinsGG p.Y192Ifs*52 | Frame Shift Del (DEL) | VAF 14/95 reads (15%) | called by pindel, varscan2*
- TRAV12-2 | c.51G>C p.W17C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TUBB4A | c.660del p.T221Pfs*13 | Frame Shift Del (DEL) | VAF 19/184 reads (10%) | called by mutect2, pindel, varscan2
- UBAP2L | c.2243del p.P748Qfs*19 | Frame Shift Del (DEL) | VAF 66/183 reads (36%) | called by mutect2, pindel, varscan2
- UBN1 | c.724del p.A242Lfs*2 | Frame Shift Del (DEL) | VAF 14/138 reads (10%) | called by pindel, varscan2
- ZFHX4 | c.7713del p.T2572Qfs*7 | Frame Shift Del (DEL) | VAF 16/91 reads (18%) | called by mutect2, pindel, varscan2
- ZNF33A | c.1897del p.E633Rfs*19 (on ENST00000458705 / NM_006974.3; = p.E634Rfs*19 on NM_006954.2) | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | called by mutect2, pindel, varscan2
- ABCA9 | c.1110C>T p.F370= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100383121; called by muse, mutect2, varscan2
- ACAD9 | c.981C>T p.C327= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs537393165, COSV100459212; called by muse, mutect2, varscan2
- ADAMTS10 | c.2413C>A p.R805= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV99546944; called by muse, mutect2, varscan2
- ADAMTS19 | c.3300T>A p.G1100= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV99178838; called by muse, mutect2, varscan2
- ADCY1 | c.3112C>A p.R1038= | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as CM145495, COSV52038469, COSV99812028; called by muse, mutect2, varscan2
- ADGRA2 | c.360C>T p.I120= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as rs771325337, COSV100177962; called by muse, mutect2, varscan2
- AFM | c.372T>C p.C124= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99888836; called by muse, mutect2
- ANGPTL4 | c.282G>A p.E94= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV100035135; called by muse, mutect2
- ANK1 | c.285G>T p.R95= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV99225322; called by muse, mutect2, varscan2
- ANTXR1 | c.1071C>A p.P357= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV100362524; called by muse, mutect2, varscan2
- ANXA11 | c.279C>T p.P93= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs763539929, COSV99627163; called by muse, mutect2, varscan2
- ASIC1 | c.117G>C p.L39= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as COSV99948071; called by muse, mutect2, varscan2
- ASPM | c.8526G>T p.R2842= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99660381; called by muse, mutect2
- ATG4B | c.417A>T p.I139= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100728654; called by muse, mutect2, varscan2
- ATP6AP1 | c.420A>T p.A140= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV100645190; called by muse, mutect2, varscan2
- ATXN3L | c.460C>A p.R154= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV101019398, COSV66075342; called by muse, mutect2, varscan2
- BAIAP2 | c.627G>C p.A209= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs746438078, COSV100348127; called by muse, mutect2, varscan2
- BTN3A3 | c.1056C>T p.I352= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs1479962224, COSV99764890; called by mutect2, varscan2
- C4BPA | c.93A>G p.P31= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV100891217; called by muse, mutect2, varscan2
- C4BPA | c.1194A>C p.S398= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100891218; called by muse, mutect2
- C7 | c.1584C>A p.P528= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100495841; called by muse, mutect2, varscan2
- CACNA2D1 | c.2658G>T p.L886= (on ENST00000356253 / NM_001366867.1; = p.L874= on NM_000722.4) | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100666670; called by muse, mutect2, varscan2
- CASR | c.1797G>T p.T599= (on ENST00000490131; = p.T676= on NM_000388.4) | Silent (SNP) | VAF 16/184 reads (9%) | catalogued as COSV99948988; called by muse, mutect2
- CEP170 | c.3420A>C p.G1140= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100317097; called by muse, mutect2, varscan2
- CHKB | c.729C>A p.I243= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as rs747689391, COSV100376658; called by muse, mutect2, varscan2
- CHL1 | c.3615C>A p.P1205= (on ENST00000397491 / NM_001253387.1; = p.P1221= on NM_006614.4) | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV56595441, COSV99852545; called by muse, mutect2, varscan2
- CNKSR2 | c.847C>A p.R283= | Silent (SNP) | VAF 6/119 reads (5%) | catalogued as COSV54266872; called by muse, mutect2
- CNTNAP2 | c.1122G>C p.V374= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV100666708; called by muse, varscan2
- CPOX | c.1161C>A p.L387= | Silent (SNP) | VAF 20/150 reads (13%) | catalogued as COSV99939117; called by muse, mutect2, varscan2
- CPT1C | c.1545G>A p.L515= | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as COSV99773471; called by muse, mutect2, varscan2
- CTPS2 | c.765G>T p.V255= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100826850; called by muse, mutect2, varscan2
- CUBN | c.9042G>T p.L3014= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as COSV100912709; called by muse, mutect2, varscan2
- CYB561A3 | c.540C>T p.F180= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV99582465; called by muse, mutect2
- D2HGDH | c.663G>T p.G221= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV100344447; called by muse, mutect2, varscan2
- DCAF12L1 | c.39G>T p.A13= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV100948300, COSV64422066; called by muse, mutect2, varscan2
- DNAJB8 | c.438G>A p.E146= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV100048308; called by muse, mutect2, varscan2
- DST | c.10044A>T p.A3348= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99756126; called by muse, mutect2
- DYRK3 | c.585G>T p.G195= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as rs909432372, COSV100895704; called by muse, mutect2, varscan2
- EPG5 | c.1779G>T p.G593= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs1026879818, COSV99957293; ClinVar: likely benign; called by muse, mutect2, varscan2
- ESR1 | c.165C>T p.P55= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV99237845, COSV99239259; called by muse, mutect2, varscan2
- ETV3L | c.243C>A p.G81= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as COSV101485587; called by muse, mutect2
- FAM135B | c.3465C>G p.L1155= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV52730280, COSV99424086; called by muse, mutect2
- FBH1 | c.1374G>T p.V458= (on ENST00000362091 / NM_178150.3; = p.V509= on NM_032807.4) | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV62982105; called by muse, mutect2, varscan2
- FBN2 | c.7290T>A p.T2430= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV99327539; called by muse, mutect2, varscan2
- FBXO40 | c.1116A>T p.P372= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV100573178; called by muse, mutect2, varscan2
- FRAS1 | c.6375G>T p.G2125= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV99352161; called by muse, mutect2, varscan2
- FRMD6 | c.1788A>G p.Q596= (on ENST00000344768 / NM_001267046.2; = p.Q588= on NM_152330.4) | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100655779; called by muse, mutect2, varscan2
- GIMAP8 | c.1644G>T p.L548= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV100217544; called by muse, mutect2, varscan2
- GPR141 | c.447C>A p.P149= | Silent (SNP) | VAF 34/169 reads (20%) | catalogued as COSV100550323, COSV57731694; called by muse, mutect2, varscan2
- GPR141 | c.448C>T p.L150= | Silent (SNP) | VAF 33/170 reads (19%) | catalogued as COSV100550327, COSV57733776; called by muse, mutect2, varscan2
- GRIK3 | c.1515G>A p.K505= | Silent (SNP) | VAF 8/113 reads (7%) | catalogued as COSV100902054; called by muse, mutect2
- GRM7 | c.918C>A p.G306= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV100736617; called by muse, mutect2, varscan2
- HBS1L | c.375G>A p.V125= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV100122095; called by muse, mutect2, varscan2
- HECTD2 | c.1656G>T p.V552= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99978577; called by muse, mutect2, varscan2
- HELZ2 | c.87G>T p.T29= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV100915590; called by muse, varscan2
- HJV | c.552A>T p.T184= (on ENST00000336751 / NM_213653.4; = p.T71= on NM_145277.5) | Silent (SNP) | VAF 32/253 reads (13%) | catalogued as COSV100382290; called by muse, mutect2, varscan2
- HSPBAP1 | c.504G>A p.L168= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV100063438, COSV60242977; called by muse, mutect2, varscan2
- HUWE1 | c.2949G>T p.T983= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99472434; called by muse, mutect2
- IGHV3-43 | c.333C>A p.A111= | Silent (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- IGKV1-33 | c.15C>A p.V5= | Silent (SNP) | VAF 8/74 reads (11%) | called by mutect2, varscan2
- IGLC2 | c.222G>A p.L74= | Silent (SNP) | VAF 4/53 reads (8%) | called by muse, mutect2
- IQSEC2 | c.1776C>A p.P592= (on ENST00000642864 / NM_001111125.3; = p.P387= on NM_015075.2) | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100944916; called by muse, mutect2, varscan2
- KCNB2 | c.858C>A p.S286= | Silent (SNP) | VAF 40/128 reads (31%) | catalogued as COSV101578789; called by muse, mutect2, varscan2
- KCNJ8 | c.909T>C p.T303= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV99557570; called by muse, mutect2, varscan2
- KCTD8 | c.297C>T p.I99= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1340573191, COSV100759568; called by muse, mutect2, varscan2
- KLHDC3 | c.1041T>A p.I347= | Silent (SNP) | VAF 67/230 reads (29%) | catalogued as COSV99763752; called by muse, mutect2, varscan2
- KLHDC4 | c.990C>T p.N330= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs142581518; called by muse, mutect2, varscan2
- KLHL34 | c.1728G>C p.L576= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV101069921; called by muse, mutect2
- KRT82 | c.1486C>A p.R496= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as rs139996519, COSV99233615; called by muse, mutect2, varscan2
- KRTAP1-5 | c.471C>A p.S157= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV100721380; called by muse, mutect2, varscan2
- KRTAP8-1 | c.114G>A p.V38= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as rs755058041, COSV100297826; called by muse, mutect2, varscan2
- LAMA2 | c.4650T>C p.P1550= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV101370464; called by muse, mutect2, varscan2
- LIPG | c.858G>T p.V286= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV99724472; called by muse, mutect2, varscan2
- LRBA | c.330C>G p.V110= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV100841571; called by muse, mutect2, varscan2
- LRP1B | c.5355C>A p.I1785= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV101257246, COSV67199602; called by muse, mutect2, varscan2
- LRRC4C | c.588G>T p.L196= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV53424797; called by muse, mutect2, varscan2
- LRRTM4 | c.1716C>A p.I572= | Silent (SNP) | VAF 32/198 reads (16%) | catalogued as COSV101298607, COSV69160990; called by muse, mutect2, varscan2
- MAB21L1 | c.942G>T p.R314= | Silent (SNP) | VAF 43/96 reads (45%) | catalogued as COSV100080370; called by muse, mutect2, varscan2
- MPDZ | c.30C>T p.A10= | Silent (SNP) | VAF 37/266 reads (14%) | catalogued as rs1005323748, COSV100062563; called by muse, mutect2, varscan2
- MTMR6 | c.1731C>T p.P577= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs540440446, COSV67810264; called by muse, mutect2, varscan2
- MTOR | c.3027G>T p.R1009= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100816200, COSV104421683; called by muse, mutect2, varscan2
- MUC5B | c.8007G>A p.V2669= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV101500356; called by muse, mutect2
- MYH4 | c.5463C>A p.A1821= | Silent (SNP) | VAF 9/132 reads (7%) | catalogued as COSV99701307; called by muse, mutect2
- NLRP12 | c.654G>A p.A218= | Silent (SNP) | VAF 44/126 reads (35%) | catalogued as rs745766441, COSV60749919; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUP133 | c.3072A>G p.P1024= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs367562007; called by muse, mutect2, varscan2
- OR10T2 | c.81G>T p.L27= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs1281824138, COSV100554962; called by muse, mutect2, varscan2
- OR1L4 | c.343C>T p.L115= | Silent (SNP) | VAF 35/130 reads (27%) | catalogued as rs1369599387, COSV99413881; called by muse, mutect2, varscan2
- OR2M5 | c.237C>A p.P79= | Silent (SNP) | VAF 82/352 reads (23%) | catalogued as COSV100822819, COSV100822863; called by muse, mutect2, varscan2
- OR2T3 | c.312C>T p.I104= | Silent (SNP) | VAF 27/123 reads (22%) | catalogued as rs762426058, COSV100613239; called by muse, mutect2, varscan2
- OR4C6 | c.15C>T p.N5= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs756959299, COSV100051636; called by muse, mutect2, varscan2
- OR4P4 | c.195A>G p.S65= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV100111745; called by muse, mutect2, varscan2
- OR4Q3 | c.459G>A p.L153= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV100057042; called by muse, mutect2, varscan2
- OR52K2 | c.411C>A p.V137= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV100355753; called by muse, mutect2, varscan2
- OR5AN1 | c.66C>A p.P22= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100004345; called by muse, mutect2, varscan2
- OR5B3 | c.435C>A p.G145= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV100511995, COSV58678412; called by muse, mutect2, varscan2
- OR8H3 | c.615C>A p.S205= | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as COSV100538983, COSV57910926; called by muse, mutect2, varscan2
- PABPC5 | c.1020C>A p.G340= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV57039993; called by muse, mutect2, varscan2
- PALLD | c.1719C>A p.S573= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV54973083, COSV99824817; called by muse, mutect2, varscan2
- PCDHGB7 | c.1416G>T p.A472= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as rs777238100, COSV54002388; called by muse, mutect2, varscan2
- PHF21A | c.465C>T p.T155= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV99138557; called by mutect2, varscan2
- PLXNA4 | c.2349C>A p.V783= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV100324397; called by muse, mutect2, varscan2
- PLXNB1 | c.675G>T p.G225= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99602859; called by muse, mutect2, varscan2
- PODN | c.939C>A p.R313= (on ENST00000395871; = p.R265= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 37/229 reads (16%) | catalogued as rs138179023, COSV100439598; called by muse, mutect2, varscan2
- POLR2H | c.51G>A p.P17= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs765439305, COSV99658586; called by mutect2, varscan2
- PPBP | c.276C>A p.V92= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs773999304, COSV99933011, COSV99933022; called by muse, mutect2, varscan2
- PPP1R7 | c.201G>T p.V67= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99297850; called by muse, mutect2, varscan2
- PRMT6 | c.564C>G p.S188= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV100791194, COSV63655662; called by muse, mutect2, varscan2
- PSG8 | c.957C>A p.I319= | Silent (SNP) | VAF 41/150 reads (27%) | catalogued as COSV100126218; called by muse, mutect2, varscan2
- QSOX2 | c.1479G>T p.S493= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV100699763; called by muse, mutect2, varscan2
- RELCH | c.171A>T p.P57= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV99902026; called by muse, mutect2, varscan2
- RIMS2 | c.1656G>T p.T552= (on ENST00000666250 / NM_001348490.2; = p.T360= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV99161239, COSV99169677; called by muse, mutect2, varscan2
- RNF113A | c.93A>G p.R31= | Silent (SNP) | VAF 30/245 reads (12%) | catalogued as COSV65097104; called by muse, mutect2, varscan2
- RUVBL1 | c.552A>T p.R184= | Silent (SNP) | VAF 55/186 reads (30%) | catalogued as COSV100494172; called by muse, mutect2, varscan2
- RYR2 | c.12825C>A p.T4275= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs775760742, COSV100770295; called by muse, mutect2, varscan2
- SAP130 | c.1332G>T p.R444= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV99384693; called by muse, mutect2, varscan2
- SAXO1 | c.234T>A p.P78= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV101000161; called by muse, mutect2, varscan2
- SCAMP5 | c.288C>T p.A96= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs1474274569, COSV100723831; called by muse, mutect2, varscan2
- SDF2 | c.234A>T p.T78= | Silent (SNP) | VAF 60/167 reads (36%) | catalogued as rs746151655, COSV99897901; called by muse, mutect2, varscan2
- SEMA5A | c.1899G>T p.V633= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs748950563, COSV101228288; called by muse, mutect2, varscan2
- SIPA1L2 | c.1368C>G p.S456= | Silent (SNP) | VAF 23/174 reads (13%) | catalogued as COSV99477592, COSV99478298; called by muse, mutect2, varscan2
- SLAMF7 | c.918T>A p.T306= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100833283; called by muse, mutect2, varscan2
- SLC17A6 | c.474C>A p.A158= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV99581144; called by muse, mutect2
- SLC6A18 | c.195C>A p.V65= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV99722325; called by muse, mutect2, varscan2
- SLITRK1 | c.1665C>T p.D555= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs367698408; called by muse, mutect2, varscan2
- SLITRK1 | c.1530G>A p.P510= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV100999801; called by muse, mutect2, varscan2
- SPATA31A1 | c.3678G>T p.A1226= | Silent (SNP) | VAF 56/273 reads (21%) | called by muse, mutect2, varscan2
- ST18 | c.1734C>A p.I578= | Silent (SNP) | VAF 46/245 reads (19%) | catalogued as COSV52513180, COSV99389679; called by muse, mutect2, varscan2
- ST18 | c.1428C>T p.F476= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs1207048601, COSV52505785; called by muse, mutect2, varscan2
- SVIL | c.3705C>A p.P1235= (on ENST00000355867 / NM_021738.3; = p.P809= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- TAF1 | c.2439C>A p.A813= (on ENST00000373790 / NM_138923.4; = p.A834= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV99335776; called by muse, mutect2, varscan2
- TBC1D25 | c.1608C>A p.S536= | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as COSV100952163; called by muse, mutect2, varscan2
- TERT | c.1857C>G p.S619= | Silent (SNP) | VAF 18/188 reads (10%) | catalogued as COSV99718413; called by muse, mutect2
- TGIF2LX | c.360C>A p.P120= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as COSV99383383; called by muse, mutect2, varscan2
- TOLLIP | c.633C>T p.P211= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs985620778, COSV99719384, COSV99719566; called by muse, mutect2, varscan2
- TRIM24 | c.1671G>A p.Q557= (on ENST00000343526 / NM_015905.3; = p.Q523= on NM_003852.4) | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV100630963; called by muse, mutect2
- TRIM58 | c.924C>A p.A308= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs775876778, COSV100825096, COSV63569313; called by muse, mutect2, varscan2
- TRO | c.891C>G p.P297= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV99436459; called by muse, mutect2
- TTC7A | c.373C>T p.L125= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as COSV99766440; called by muse, mutect2, varscan2
- VASH2 | c.669G>T p.R223= (on ENST00000517399 / NM_001301056.2; = p.R179= on NM_024749.5) | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV55118839, COSV99663539; called by muse, mutect2
- ZBTB33 | c.826C>T p.L276= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV100434188; called by muse, mutect2, varscan2
- ZG16B | c.207C>T p.D69= | Silent (SNP) | VAF 27/143 reads (19%) | catalogued as COSV101206759; called by muse, mutect2, varscan2
- ZNF443 | c.357T>C p.N119= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV100042150; called by muse, mutect2, varscan2
- ZNF668 | c.1821G>T p.L607= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV100336672; called by muse, mutect2, varscan2
- ZNRF4 | c.378C>A p.P126= | Silent (SNP) | VAF 57/142 reads (40%) | catalogued as COSV55772795, COSV99706514; called by muse, mutect2, varscan2
- AP001042.1 | n.2299C>A | RNA (SNP) | VAF 22/101 reads (22%) | called by muse, mutect2, varscan2
- ATP6V1B1 | c.*1C>G | 3'UTR (SNP) | VAF 26/116 reads (22%) | catalogued as COSV99314126; called by muse, mutect2
- BAGE2 | n.305C>A | RNA (SNP) | VAF 5/89 reads (6%) | catalogued as rs1291840649; called by muse, mutect2
- CCDC140 | n.499C>T | RNA (SNP) | VAF 13/44 reads (30%) | catalogued as COSV99735119; called by muse, mutect2, varscan2
- DCHS2 | n.6978C>T | RNA (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100601788; called by muse, mutect2
- DENND10P1 | n.1155G>A | RNA (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- DIRC1 | n.332G>T | RNA (SNP) | VAF 23/90 reads (26%) | catalogued as COSV100352756, COSV57365993; called by muse, mutect2, varscan2
- MASP1 | c.1303+5363del | Intron (DEL) | VAF 14/134 reads (10%) | called by mutect2, pindel, varscan2
- MGAM | c.4618+126T>C | Intron (SNP) | VAF 11/60 reads (18%) | catalogued as COSV101527492; called by muse, mutect2, varscan2
- NXT2 | c.-19C>A | 5'UTR (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99484134; called by muse, mutect2, varscan2
- OR2T1 | c.-8dup | 5'UTR (INS) | VAF 16/67 reads (24%) | called by mutect2, varscan2
- OR2T1 | c.-6_-5del | 5'UTR (DEL) | VAF 17/67 reads (25%) | called by mutect2, pindel*, varscan2
- SLC6A15 | c.756+93C>A | Intron (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99880813, COSV99881313; called by muse, mutect2, varscan2
- THUMPD1 | c.*1G>A | 3'UTR (SNP) | VAF 6/38 reads (16%) | catalogued as rs765825576, COSV101189715; called by muse, mutect2
- TRPM3 | c.979+17837G>T | Intron (SNP) | VAF 22/76 reads (29%) | catalogued as COSV100677390; called by muse, mutect2, varscan2
- USP17L30 | chr4:9359311 A>C | 5'Flank (SNP) | VAF 22/143 reads (15%) | catalogued as rs765390272; called by muse, mutect2, varscan2
